Somatic mutation profile of tumor specimen SM-JU34G (aliquot 7316UP-361) from CPTAC case C330255, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Tumor grade: G4.
Specimen SM-JU34G: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54fc0a19-f074-4841-a1ac-4788beb18c96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105212 (Blood Derived Normal), aliquot 7316UP-361-1105212; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06589efb-d718-4646-bd54-819e3258d840

The open-access MAF lists 68 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Intron 6, Nonsense Mutation 4, 5'Flank 2, 5'UTR 1, Frame Shift Del 1, RNA 1, Splice Site 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>A p.G1049S | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 154/376 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs750641202, COSV58639892; called by muse, mutect2, varscan2
- AFF2 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 113/235 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99663577; called by muse, mutect2, varscan2
- AK7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs767780619, COSV50871179; called by muse, mutect2, varscan2
- DDX3X | c.982G>A p.D328N (on ENST00000399959; = p.D329N on NM_001356.5) | Missense Mutation (SNP) | VAF 270/636 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101302320, COSV101302559; called by muse, mutect2, varscan2
- EMILIN3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 153/604 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs751404791, COSV60035122; called by muse, mutect2, varscan2
- GAD2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 221/295 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757006706; called by muse, mutect2, varscan2
- GATA6 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 258/630 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1372369528, COSV52528013; called by muse, varscan2
- H2BC1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 146/373 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs776852235; called by muse, mutect2, varscan2
- MUC12 | c.13126A>G p.S4376G (on ENST00000379442; = p.S4233G on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (1); catalogued as rs200462783; called by mutect2, varscan2
- MUC17 | c.9893C>T p.T3298M | Missense Mutation (SNP) | VAF 90/346 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs763282881; called by muse, mutect2, varscan2
- NLRP8 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs376081039; called by muse, mutect2, varscan2
- NPC1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 208/510 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs140786703; called by muse, mutect2, varscan2
- PCDH1 | c.2165C>G p.S722C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54615324; called by muse, mutect2, varscan2
- PCLO | c.9716G>A p.R3239H | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779385664, COSV61613933; called by muse, mutect2, varscan2
- PPP3CB | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 128/160 reads (80%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV55019745; called by muse, mutect2, varscan2
- RBMXL3 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs782526835; called by muse, mutect2, varscan2
- RGS3 | c.3504C>A p.F1168L (on ENST00000350696 / NM_001282923.2; = p.F887L on NM_130795.4) | Missense Mutation (SNP) | VAF 139/354 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV100637009; called by muse, mutect2, varscan2
- RPH3A | c.805C>T p.R269W (on ENST00000389385 / NM_001143854.2; = p.R265W on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/377 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs760123095, COSV101231776; called by muse, varscan2
- SRPX | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs750284952, COSV100656054; called by muse, mutect2, varscan2
- STPG3 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 244/615 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1390662039; called by muse, mutect2, varscan2
- TP53TG5 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 424/1535 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs780299271, COSV101022354, COSV65577436; called by muse, mutect2, varscan2
- CUBN | c.4133del p.R1378Lfs*85 | Frame Shift Del (DEL) | VAF 439/732 reads (60%) | called by mutect2, pindel, varscan2
- DNAH9 | c.2506C>T p.L836F | Missense Mutation (SNP) | VAF 159/411 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EGFL6 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EGFR | c.761T>G p.F254C | Missense Mutation (SNP) | VAF 452/10326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSTA3 | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 152/366 reads (42%) | called by muse, mutect2, varscan2
- MYO10 | c.4253G>A p.W1418* | Nonsense Mutation (SNP) | VAF 129/352 reads (37%) | called by muse, mutect2, varscan2
- NFATC1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 198/479 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.4724A>T p.E1575V | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OR4S2 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 193/484 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OXGR1 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PKP2 | c.1510+1G>A p.X504_splice | Splice Site (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- PROS1 | c.1038C>G p.H346Q | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2
- PRSS16 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 193/495 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SMOX | c.1019A>T p.Q340L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TBC1D8B | c.2941A>T p.I981F | Missense Mutation (SNP) | VAF 122/277 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- TDRD7 | c.2699A>T p.E900V | Missense Mutation (SNP) | VAF 191/464 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TMTC1 | c.2620C>T p.Q874* (on ENST00000539277 / NM_001193451.2; = p.Q766* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 115/298 reads (39%) | called by muse, mutect2, varscan2
- WDFY3 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 228/539 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZC2HC1C | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ZCCHC8 | c.1077C>G p.Y359* | Nonsense Mutation (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- ZNF416 | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 83/290 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ALDH3B1 | c.1134G>T p.L378= | Silent (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- BRINP3 | c.912T>C p.L304= | Silent (SNP) | VAF 89/207 reads (43%) | called by muse, mutect2, varscan2
- CEP350 | c.2943A>G p.S981= | Silent (SNP) | VAF 90/299 reads (30%) | called by muse, mutect2, varscan2
- CFAP20DC | c.1767A>G p.Q589= | Silent (SNP) | VAF 264/635 reads (42%) | called by muse, mutect2, varscan2
- GAS2 | c.738A>G p.K246= | Silent (SNP) | VAF 172/414 reads (42%) | catalogued as rs529708585; called by muse, mutect2, varscan2
- IBSP | c.351C>T p.D117= | Silent (SNP) | VAF 111/341 reads (33%) | catalogued as rs779776336, COSV56896798; called by muse, mutect2, varscan2
- LRRC3B | c.570C>T p.N190= | Silent (SNP) | VAF 87/238 reads (37%) | catalogued as rs375239096; called by muse, mutect2, varscan2
- MTUS2 | c.147C>T p.D49= | Silent (SNP) | VAF 131/297 reads (44%) | catalogued as rs183635259, COSV70917993; called by muse, mutect2, varscan2
- MYRF | c.1617C>T p.S539= (on ENST00000278836 / NM_001127392.3; = p.S530= on NM_013279.4) | Silent (SNP) | VAF 167/388 reads (43%) | catalogued as COSV99607504; called by muse, mutect2, varscan2
- RAB35 | c.297C>G p.V99= | Silent (SNP) | VAF 117/359 reads (33%) | called by muse, mutect2, varscan2
- TRRAP | c.8565C>T p.C2855= (on ENST00000359863 / NM_001244580.1; = p.C2837= on NM_003496.3) | Silent (SNP) | VAF 175/683 reads (26%) | catalogued as rs777625422, COSV62840828; called by muse, mutect2, varscan2
- VPS25 | c.348C>T p.S116= | Silent (SNP) | VAF 124/400 reads (31%) | catalogued as rs1051997463, COSV53822367; called by muse, mutect2, varscan2
- ZCCHC14 | c.1893C>T p.H631= (on ENST00000268616; = p.H768= on NM_015144.3) | Silent (SNP) | VAF 135/280 reads (48%) | catalogued as rs1343391889; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156877 G>A | 3'Flank (SNP) | VAF 112/294 reads (38%) | catalogued as rs375515044; called by muse, mutect2, varscan2
- AGPAT2 | c.-21C>T | 5'UTR (SNP) | VAF 141/288 reads (49%) | catalogued as rs1340169329; called by muse, mutect2, varscan2
- ATP5F1B | c.310+100del | Intron (DEL) | VAF 50/183 reads (27%) | called by mutect2, pindel, varscan2
- DEUP1 | c.1638+77C>T | Intron (SNP) | VAF 40/103 reads (39%) | catalogued as rs186846330; called by muse, mutect2
- DNMT1 | c.1041+35G>A | Intron (SNP) | VAF 285/1110 reads (26%) | catalogued as rs561688819; called by muse, mutect2, varscan2
- FAM13B | chr5:138036651 del TAAC | 5'Flank (DEL) | VAF 57/125 reads (46%) | called by mutect2, pindel
- FKBP6 | c.57+45C>T | Intron (SNP) | VAF 122/626 reads (19%) | catalogued as rs781951342; called by muse, mutect2, varscan2
- GMNN | c.-25-35C>T | Intron (SNP) | VAF 131/288 reads (45%) | catalogued as rs1026591784; called by muse, mutect2, varscan2
- MMAB | c.*3065G>A | 3'UTR (SNP) | VAF 228/613 reads (37%) | catalogued as rs981927317; called by muse, mutect2, varscan2
- OR5P1P | n.733G>A | RNA (SNP) | VAF 62/132 reads (47%) | catalogued as rs1182308743; called by muse, mutect2, varscan2
- STAU1 | c.206-4874A>G | Intron (SNP) | VAF 115/502 reads (23%) | called by muse, varscan2
- TRHDE | chr12:72271904 C>G | 5'Flank (SNP) | VAF 119/280 reads (43%) | catalogued as rs1194899367; called by muse, mutect2, varscan2
